Gene-level copy-number profile of tumor specimen TCGA-06-0402-01A from TCGA case TCGA-06-0402, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.3 years (26,059 days).
Specimen TCGA-06-0402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.360438e0-5cc4-4623-a73b-1663aac984c1.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,190 have no estimate.
https://portal.gdc.cancer.gov/files/ca3dec5f-78bf-45e8-b579-3f4cc8ed5fbd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,671; copy number 2: 46,071; copy number 3: 6,360; copy number 4: 153; copy number 5: 26; copy number 6: 42; copy number 7: 80; copy number 8: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0402-01): tumor purity 0.94, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 178 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,028,130–180,871,005, 54 genes, copy number 7: AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1.
- chr3:180,989,762–183,116,075, 35 genes, copy number 7–8 (within-gene range 3–8): SOX2-OT, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1.
- chr3:191,952,349–192,119,864, 4 genes, copy number 7: AC026320.2, AC026320.1, AC026320.3, RN7SKP222.
- chr3:192,238,037–192,283,097, 1 gene, copy number 7: FGF12-AS1.
- chr4:53,986,587–54,298,245, 10 genes, copy number 5: RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA.
- chr7:16,646,131–16,888,885, 8 genes, copy number 6 (within-gene range 3–6): BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 6: AC098592.1.
- chr7:23,811,144–24,255,719, 4 genes, copy number 5: TPT1P7, AC003087.1, RNA5SP228, AC004485.1.
- chr7:32,580,949–33,109,404, 19 genes, copy number 6 (within-gene range 3–6): DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr7:33,128,988–33,380,886, 4 genes, copy number 6: AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:34,346,512–34,878,332, 5 genes, copy number 6 (within-gene range 2–6): NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P.
- chr7:37,683,843–38,025,695, 5 genes, copy number 6 (within-gene range 2–6): EPDR1, GPR141BP, AC018634.1, NME8, SFRP4.
- chr7:38,383,704–38,932,394, 5 genes, copy number 5 (within-gene range 2–5): AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41.
- chr7:38,980,370–39,013,551, 1 gene, copy number 5: POU6F2-AS2.
- chr7:69,598,296–70,838,013, 2 genes, copy number 5 (within-gene range 2–5): AUTS2, AC073873.1.
- chr7:77,798,792–79,453,667, 9 genes, copy number 8 (within-gene range 2–8): PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1.
- chr7:79,008,988–79,177,210, 4 genes, copy number 5: MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2.
- chr10:78,176,928–78,675,109, 7 genes, copy number 7 (within-gene range 2–7): AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71.

Autosomal genes at a single copy (total copy number 1): 2,671. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
